Gene-level copy-number profile of tumor specimen CDDP-ABIW-TTP1-A from CDDP_EAGLE case CDDP-ABIW, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40 years.
Specimen CDDP-ABIW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bc81dd90-b9ee-4f93-aec4-3e47e545fc79.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABIW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,740 have no estimate.
https://portal.gdc.cancer.gov/files/1d98c8b6-41ca-47f2-89c8-9d5a6a277a68

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 166; copy number 2: 3,050; copy number 3: 3,841; copy number 4: 23,746; copy number 5: 11,355; copy number 6: 10,923; copy number 7: 1,427; copy number 8: 2,189; copy number 9: 788; copy number 10: 258; copy number 11: 658; copy number 12: 161; copy number 13: 149; copy number 14: 90; copy number 15: 3; copy number 16: 23; copy number 17: 11; copy number 18: 10; copy number 19: 1; copy number 21: 7; copy number 22: 20; copy number 28: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,573,801–248,635,091, 5 genes: OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,180 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:160,190,575–175,148,075, 367 genes, copy number 11–21 (broad region; genes not listed).
- chr7:63,011,463–64,030,105, 60 genes, copy number 11–16: RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4, AC006455.7, ZNF733P, AC006455.1, ARAFP3, AC006455.6, AC006455.5, AC006455.2, AC006455.3, AC006455.4, VN1R31P, VN1R32P, AC073188.3, AC073188.4, AC073188.2, AC073188.1, AC073188.5, AC073188.6, SLC25A1P2, VN1R33P, ARAFP2, ZNF734P, AC006457.1, SEPTIN7P5, PHKG1P2, SLC29A4P2, TNRC18P2, MIR4283-2, AC006015.1, AC079355.1, CICP24, AC079355.2, AC092634.5, AC092634.2, AC092634.4, GABPAP, LINC02848, NMD3P1, AC092634.3, AC092634.8, SLC25A1P3, VN1R34P, ARAFP1, AC092634.7, VN1R35P, VN1R36P, AC092634.1, AC092634.6, ZNF722P, LINC01005.
- chr7:69,026,433–83,162,930, 240 genes, copy number 9–14 (broad region; genes not listed).
- chr7:90,466,424–91,210,590, 1 gene, copy number 9 (within-gene range 8–9): CDK14.
- chr7:91,030,149–101,569,006, 281 genes, copy number 9 (broad region; genes not listed).
- chr7:102,433,106–123,199,972, 280 genes, copy number 11–14 (within-gene range 7–14) (broad region; genes not listed).
- chr9:41,644,438–41,648,035, 3 genes, copy number 16: AL591926.7, AL591926.6, AL591926.5.
- chr9:64,810,865–64,811,429, 1 gene, copy number 12: BNIP3P4.
- chr10:65,054,460–65,248,792, 3 genes, copy number 9: NEK4P3, MYL6P3, AL513321.1.
- chr10:87,201,647–87,342,612, 3 genes, copy number 9 (within-gene range 6–9): NUTM2A-AS1, AL157893.2, AL157893.1.
- chr11:11,270,877–11,622,005, 1 gene, copy number 9 (within-gene range 6–9): GALNT18.
- chr11:11,570,084–11,573,782, 1 gene, copy number 9: AC104031.1.
- chr17:8,413,131–9,244,897, 15 genes, copy number 11: NDEL1, MYH10, RNU7-43P, PPIAP52, AC025518.1, CCDC42, SPDYE4, MFSD6L, PIK3R6, PIK3R5, AC002091.2, AC002091.1, NTN1, AC005695.1, AC005695.3.
- chr17:37,375,985–38,405,593, 31 genes, copy number 9 (within-gene range 5–9): C17orf78, AC243654.3, TADA2A, AC243654.1, AC243654.2, DUSP14, SYNRG, AC243585.2, DDX52, MIR378J, AC243571.2, AC243585.1, HNF1B, AC243571.1, YWHAEP7, RNU6-489P, TBC1D3K, 5S_rRNA, TBC1D3L, TBC1D3D, TBC1D3C, AC233968.1, Y_RNA, TBC1D3E, RNA5SP526, TBC1D3, NPEPPSP1, Y_RNA, MRPL45, GPR179, SOCS7.
- chr17:39,757,718–57,684,689, 695 genes, copy number 9–28 (within-gene range 7–28) (broad region; genes not listed).
- chr17:58,157,028–59,707,626, 62 genes, copy number 11–19 (within-gene range 7–19) (broad region; genes not listed).
- chr17:66,835,117–68,115,518, 38 genes, copy number 11: CACNG5, RNA5SP446, CACNG4, AC005544.1, AC005544.2, CACNG1, HELZ, AC007448.3, RPL36AP48, AC007448.5, AC007448.4, RNA5SP447, AC007448.1, AC007448.2, PSMD12, PITPNC1, Y_RNA, RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674.
- chr17:68,413,623–70,368,916, 36 genes, copy number 13–22 (within-gene range 4–22): AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1, LINC01482, AC011591.2, AC011591.1, ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16, KCNJ2-AS1, KCNJ2, CALM2P1, AC011990.1.
- chr17:72,645,949–73,092,712, 1 gene, copy number 10 (within-gene range 4–10): SLC39A11.
- chr17:72,818,836–72,839,718, 2 genes, copy number 10: AC080037.1, AC011120.1.
- chr17:81,976,807–82,031,151, 3 genes, copy number 15: ASPSCR1, CENPX, LRRC45.
- chr21:12,999,676–13,489,176, 10 genes, copy number 9 (within-gene range 5–9): AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2.
- chr21:25,880,550–26,171,128, 2 genes, copy number 9 (within-gene range 6–9): APP, AP001442.1.
- chr21:26,158,091–29,288,205, 43 genes, copy number 9 (within-gene range 6–9): AP001439.1, AP000229.1, RNU6-926P, AP001595.1, AP001596.1, CYYR1-AS1, AP001596.2, CYYR1, ADAMTS1, AP001599.1, ADAMTS5, MIR4759, GPX1P2, AP001605.1, AP001604.1, EIF4A1P1, RPL10P1, NCSTNP1, LINC01673, LINC00113, AJ006995.1, LINC00314, LINC01697, LINC01695, AF165147.1, LINC00161, N6AMT1, HSPD1P7, THUMPD1P1, LTN1, RPL23P2, RWDD2B, AF129075.2, USP16, CCT8, AF129075.1, AF129075.3, MAP3K7CL, RPL12P9, Y_RNA, U3, AF124730.1, LINC00189.
- chr21:29,222,321–29,223,257, 1 gene, copy number 9 (within-gene range 6–9): GAPDHP14.

Autosomal genes at a single copy (total copy number 1): 165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
